Somatic mutation profile of tumor specimen a03d1103-b809-42c4-ad5c-5aff58 (aliquot a03d1103-b809-42c4-ad5c-5aff58_D6) from CPTAC case 18OV001, project CPTAC-2 (Ovary — Cystic, Mucinous and Serous Neoplasms). Sex at birth: female; Primary diagnosis: Serous adenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IC.
Specimen a03d1103-b809-42c4-ad5c-5aff58: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fc64c5f9-9247-4376-808b-968e4b878cdc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen b6a10ca7-bb8c-4d2b-a20d-19386e (Blood Derived Normal), aliquot b6a10ca7-bb8c-4d2b-a20d-19386e_D1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/af9583e0-4ab2-4026-86d3-ee2e2e90e2b8

The open-access MAF lists 68 somatic variants for this specimen: 50 protein-altering or splice-affecting, 8 silent, 10 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 44, Silent 8, Frame Shift Del 3, 3'UTR 3, Intron 3, 3'Flank 2, Splice Site 2, RNA 1, 5'UTR 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.734G>A p.G245D | Missense Mutation (SNP) | VAF 226/248 reads (91%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121912656, CM010464, CM900209, COSV52666323, COSV52667838, COSV52745465; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- AJAP1 | c.244C>T p.R82W | Missense Mutation (SNP) | VAF 21/30 reads (70%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.736); catalogued as rs1469028053; called by muse, mutect2, varscan2
- ANKRD17 | c.2857A>T p.I953F | Missense Mutation (SNP) | VAF 129/339 reads (38%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.033); catalogued as rs746461793; called by muse, mutect2, varscan2
- ANXA11 | c.1139A>G p.N380S | Missense Mutation (SNP) | VAF 29/196 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.646); catalogued as rs749966764; called by muse, mutect2, varscan2
- BCAN | c.820C>T p.R274W | Missense Mutation (SNP) | VAF 88/238 reads (37%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.849); catalogued as rs574942413, COSV61256435; called by muse, mutect2, varscan2
- DEFA4 | c.145G>A p.D49N | Missense Mutation (SNP) | VAF 27/79 reads (34%) | SIFT tolerated (0.37); PolyPhen probably damaging (1); catalogued as COSV52404561; called by muse, mutect2, varscan2
- DHX37 | c.2227G>T p.A743S | Missense Mutation (SNP) | VAF 31/48 reads (65%) | SIFT tolerated (0.76); PolyPhen benign (0.046); catalogued as COSV58137311; called by muse, mutect2, varscan2
- DNAH9 | c.3200C>T p.T1067M | Missense Mutation (SNP) | VAF 182/438 reads (42%) | SIFT deleterious (0.03); PolyPhen benign (0.223); catalogued as rs200139406; called by muse, mutect2, varscan2
- GPR176 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.67); catalogued as rs916565926; called by muse, mutect2, varscan2
- HSPA2 | c.211G>A p.A71T | Missense Mutation (SNP) | VAF 24/423 reads (6%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.538); catalogued as rs756808874; called by muse, mutect2
- KBTBD8 | c.1747C>T p.R583W | Missense Mutation (SNP) | VAF 54/296 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as rs760241546; called by muse, mutect2, varscan2
- LMF1 | c.874G>A p.G292R | Missense Mutation (SNP) | VAF 59/240 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs764154907; called by muse, mutect2, varscan2
- LUZP2 | c.673C>A p.P225T | Missense Mutation (SNP) | VAF 29/132 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.003); catalogued as rs200569816, COSV100421462, COSV61205595; called by muse, mutect2, varscan2
- MCTP1 | c.1283G>A p.R428K | Missense Mutation (SNP) | VAF 29/62 reads (47%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0.015); catalogued as rs965724277; called by muse, mutect2, varscan2
- MUC19 | c.368G>A p.S123N | Missense Mutation (SNP) | VAF 24/75 reads (32%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.862); catalogued as COSV70100870; called by muse, mutect2, varscan2
- MYO15A | c.8428G>A p.G2810S | Missense Mutation (SNP) | VAF 211/467 reads (45%) | SIFT tolerated (0.76); PolyPhen benign (0); catalogued as rs757713092, COSV52755190; called by muse, mutect2, varscan2
- NDUFB2 | c.215G>A p.R72H | Missense Mutation (SNP) | VAF 51/159 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.014); catalogued as rs779245244, COSV99199971; called by muse, mutect2, varscan2
- NSUN6 | c.1153G>T p.A385S | Missense Mutation (SNP) | VAF 24/130 reads (18%) | SIFT tolerated (0.11); PolyPhen benign (0.377); catalogued as rs1374441619; called by muse, mutect2, varscan2
- OR2A14 | c.895G>A p.A299T | Missense Mutation (SNP) | VAF 61/194 reads (31%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.465); catalogued as rs776312245, COSV101376504, COSV68718729; called by muse, mutect2, varscan2
- OR4C11 | c.385C>T p.R129C | Missense Mutation (SNP) | VAF 73/235 reads (31%) | SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs559156783, COSV56353261; called by muse, mutect2, varscan2
- SAMD9L | c.2660A>G p.Y887C | Missense Mutation (SNP) | VAF 66/200 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as rs750736998; called by muse, mutect2, varscan2
- TELO2 | c.416C>T p.A139V | Missense Mutation (SNP) | VAF 146/331 reads (44%) | SIFT tolerated (0.13); PolyPhen benign (0); catalogued as rs566609528; called by muse, mutect2, varscan2
- AFF3 | c.31G>C p.E11Q | Missense Mutation (SNP) | VAF 6/22 reads (27%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.938); called by muse, varscan2
- BEND2 | c.1229T>A p.M410K | Missense Mutation (SNP) | VAF 19/48 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.281); called by muse, mutect2, varscan2
- BRWD3 | c.1232+1G>A p.X411_splice | Splice Site (SNP) | VAF 58/135 reads (43%) | called by muse, mutect2, varscan2
- CARMIL2 | c.843C>G p.S281R | Missense Mutation (SNP) | VAF 59/275 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.537); called by muse, mutect2, varscan2
- CPEB2 | c.254C>G p.P85R | Missense Mutation (SNP) | VAF 34/111 reads (31%) | SIFT tolerated, low confidence (0.1); called by muse, mutect2, varscan2
- EIF5B | c.2080C>G p.R694G | Missense Mutation (SNP) | VAF 20/83 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.43); called by muse, mutect2, varscan2
- FAM47C | c.2065C>G p.H689D | Missense Mutation (SNP) | VAF 162/442 reads (37%) | SIFT tolerated (0.07); PolyPhen benign (0.089); called by mutect2, varscan2
- FREM2 | c.1115G>A p.S372N | Missense Mutation (SNP) | VAF 87/227 reads (38%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.674); called by muse, mutect2, varscan2
- GFOD1 | c.968G>A p.R323Q | Missense Mutation (SNP) | VAF 139/297 reads (47%) | SIFT tolerated (0.15); PolyPhen benign (0.125); called by muse, mutect2, varscan2
- GYPB | c.112A>T p.S38C | Missense Mutation (SNP) | VAF 103/341 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- GZF1 | c.1294G>C p.D432H | Missense Mutation (SNP) | VAF 47/216 reads (22%) | SIFT tolerated (0.25); PolyPhen benign (0.028); called by muse, mutect2, varscan2
- HSBP1L1 | c.211dup p.M71Nfs*27 | Frame Shift Ins (INS) | VAF 57/121 reads (47%) | called by mutect2, pindel, varscan2
- KRT7 | c.1178G>C p.R393P | Missense Mutation (SNP) | VAF 68/111 reads (61%) | SIFT deleterious (0); PolyPhen possibly damaging (0.478); called by muse, mutect2, varscan2
- LAMA1 | c.7478A>G p.K2493R | Missense Mutation (SNP) | VAF 27/287 reads (9%) | SIFT tolerated (0.21); PolyPhen benign (0.003); called by muse, mutect2
- MYO16 | c.2579G>T p.W860L | Missense Mutation (SNP) | VAF 49/223 reads (22%) | SIFT tolerated (0.15); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR2A14 | c.502T>G p.C168G | Missense Mutation (SNP) | VAF 44/620 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2
- OR2F1 | c.895G>C p.G299R | Missense Mutation (SNP) | VAF 91/244 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.06); called by muse, mutect2, varscan2
- PLXNA4 | c.1743del p.Y582Tfs*63 | Frame Shift Del (DEL) | VAF 55/220 reads (25%) | called by mutect2, pindel, varscan2
- PLXNB2 | c.759C>A p.D253E | Missense Mutation (SNP) | VAF 198/431 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PPP4R3C | c.1258A>T p.I420F | Missense Mutation (SNP) | VAF 17/179 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); called by muse, mutect2
- RYR1 | c.14364+2dup p.X4788_splice | Splice Site (INS) | VAF 120/358 reads (34%) | called by mutect2, pindel, varscan2
- SCRN2 | c.77C>T p.A26V | Missense Mutation (SNP) | VAF 12/106 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- SLC9A6 | c.641A>G p.D214G | Missense Mutation (SNP) | VAF 90/214 reads (42%) | SIFT tolerated (0.16); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- SMARCA2 | c.1342C>A p.H448N | Missense Mutation (SNP) | VAF 9/122 reads (7%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.988); called by muse, mutect2
- TESK1 | c.1691A>T p.E564V | Missense Mutation (SNP) | VAF 55/170 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0.383); called by muse, mutect2, varscan2
- TEX37 | c.522del p.L175* | Frame Shift Del (DEL) | VAF 42/189 reads (22%) | called by mutect2, pindel, varscan2
- TRIM6 | c.415del p.E139Sfs*10 | Frame Shift Del (DEL) | VAF 45/163 reads (28%) | called by mutect2, pindel, varscan2
- UNC5D | c.1546C>G p.H516D | Missense Mutation (SNP) | VAF 21/379 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.003); called by muse, mutect2
- APOB | c.663C>A p.G221= | Silent (SNP) | VAF 219/881 reads (25%) | called by muse, mutect2, varscan2
- C10orf71 | c.3807G>A p.A1269= | Silent (SNP) | VAF 97/419 reads (23%) | catalogued as rs935838327, COSV60504387; called by muse, mutect2, varscan2
- CASS4 | c.1441A>C p.R481= | Silent (SNP) | VAF 92/424 reads (22%) | called by muse, mutect2, varscan2
- DCAF5 | c.2736T>C p.A912= | Silent (SNP) | VAF 40/148 reads (27%) | called by muse, mutect2, varscan2
- ENAH | c.1191C>T p.A397= | Silent (SNP) | VAF 32/111 reads (29%) | catalogued as rs757602062; called by muse, mutect2, varscan2
- MAML1 | c.963T>G p.S321= | Silent (SNP) | VAF 58/127 reads (46%) | called by muse, mutect2, varscan2
- OR10G3 | c.54G>A p.P18= | Silent (SNP) | VAF 32/102 reads (31%) | catalogued as rs764237991; called by muse, mutect2, varscan2
- TIMM8A | c.252C>G p.T84= | Silent (SNP) | VAF 65/136 reads (48%) | called by muse, mutect2, varscan2
- DLG3 | c.1773+804A>T | Intron (SNP) | VAF 8/122 reads (7%) | called by muse, mutect2
- FAM90A25P | n.89C>T | RNA (SNP) | VAF 8/50 reads (16%) | called by mutect2, varscan2
- JPH3 | c.2167-1198G>T | Intron (SNP) | VAF 117/499 reads (23%) | called by muse, mutect2, varscan2
- JPH3 | chr16:87702388 G>A | 3'Flank (SNP) | VAF 32/99 reads (32%) | catalogued as rs1317143024; called by muse, mutect2, varscan2
- LGI2 | c.*3667C>A | 3'UTR (SNP) | VAF 30/114 reads (26%) | called by muse, mutect2
- LGI2 | c.*3666T>A | 3'UTR (SNP) | VAF 30/114 reads (26%) | called by muse, mutect2
- METTL6 | c.*29G>A | 3'UTR (SNP) | VAF 15/33 reads (45%) | called by muse, mutect2, varscan2
- SOX9 | c.-47G>T | 5'UTR (SNP) | VAF 65/122 reads (53%) | called by muse, mutect2, varscan2
- STK26 | c.273+615C>A | Intron (SNP) | VAF 30/99 reads (30%) | called by muse, mutect2, varscan2
- TRIM73 | chr7:75410196 C>A | 3'Flank (SNP) | VAF 152/303 reads (50%) | called by muse, mutect2, varscan2
